Somatic mutation profile of tumor specimen TCGA-06-0154-01A (aliquot TCGA-06-0154-01A-03D-1491-08) from TCGA case TCGA-06-0154, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.8 years (20,018 days).
Specimen TCGA-06-0154-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 424c6de0-1f3a-410e-90e1-386f3622ee48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0154-10A (Blood Derived Normal), aliquot TCGA-06-0154-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a49f969a-d956-42fb-b61e-299f64000dbb

The open-access MAF lists 57 somatic variants for this specimen: 45 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 41, Silent 12, Nonsense Mutation 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 1932/2350 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51784086; called by mutect2, varscan2
- AGPAT1 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61247313; called by muse, mutect2, varscan2
- ANK3 | c.10748C>T p.T3583M | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV55042774; called by muse, mutect2, varscan2
- ANKRD6 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780403490, COSV60229575; called by muse, mutect2, varscan2
- AP3S1 | c.574T>C p.F192L | Missense Mutation (SNP) | VAF 43/242 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as COSV57475435; called by muse, mutect2, varscan2
- APBB1IP | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 79/194 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1312142200, COSV66131197; called by muse, mutect2, varscan2
- ARFGEF3 | c.6463G>A p.D2155N | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.734); catalogued as rs373010266; called by muse, mutect2, varscan2
- ARHGAP21 | c.2939C>G p.T980R | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.473); catalogued as COSV57604133; called by muse, mutect2, varscan2
- ASNS | c.1108C>T p.L370F | Missense Mutation (SNP) | VAF 43/254 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV51553510; called by muse, mutect2, varscan2
- CARMIL2 | c.1696del p.L566Wfs*29 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as COSV58030972; called by mutect2, pindel, varscan2
- CLCNKA | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 75/367 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs369364364; called by muse, mutect2, varscan2
- CNTNAP2 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.189); catalogued as rs777884519, CM1313256, COSV62148925; called by muse, mutect2, varscan2
- DNAH1 | c.9363G>A p.K3121= | Splice Region (SNP) | VAF 5/24 reads (21%) | catalogued as COSV70228995, COSV70231095; called by muse, mutect2, varscan2
- DOCK2 | c.4859G>A p.R1620Q | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.177); catalogued as rs567162342, COSV56951170; called by muse, mutect2, varscan2
- F5 | c.3765G>C p.Q1255H | Missense Mutation (SNP) | VAF 102/338 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV63122436, COSV63127389; called by muse, mutect2, varscan2
- FETUB | c.495C>A p.H165Q | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV54005196; called by muse, mutect2, varscan2
- GHRHR | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs535727568, COSV58195509, COSV58196012; called by muse, mutect2, varscan2
- GLRA3 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs771115012, COSV56857256; called by muse, mutect2, varscan2
- ISX | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs184840753; called by muse, mutect2, varscan2
- KHDRBS2 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.033); catalogued as rs778333402, COSV55440092; called by muse, mutect2, varscan2
- KLC2 | c.1384C>T p.Q462* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV57582061; called by muse, mutect2, varscan2
- KRT33B | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.149); catalogued as rs780775426, COSV52440593; called by muse, mutect2, varscan2
- LRP1 | c.3595G>C p.A1199P | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV54506240; called by muse, mutect2, varscan2
- LRRC7 | c.2464A>G p.T822A (on ENST00000651989 / NM_001370785.2; = p.T789A on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/257 reads (23%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.017); catalogued as COSV50433957; called by muse, mutect2, varscan2
- MAB21L3 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as rs761323415, COSV65673750; called by muse, mutect2, varscan2
- MCOLN3 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.271); catalogued as rs144793042; called by muse, mutect2, varscan2
- MYH2 | c.4517G>A p.R1506Q | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1049022189, COSV55434777; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR6C74 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV59606024; called by muse, mutect2, varscan2
- OR7D2 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 52/283 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.202); catalogued as rs201184916, COSV60139140; called by muse, mutect2, varscan2
- OR9G4 | c.451G>T p.G151* | Nonsense Mutation (SNP) | VAF 51/162 reads (31%) | catalogued as COSV57248150; called by muse, mutect2, varscan2
- OTOP3 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.16); catalogued as rs764432166, COSV60912746; called by muse, mutect2, varscan2
- PCDHB12 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.61); catalogued as COSV53394216, COSV53396526; called by muse, mutect2, varscan2
- PCDHGA5 | c.1111G>A p.V371I | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.358); catalogued as rs749640886, COSV53974505; called by muse, mutect2, varscan2
- PIK3C2G | c.2142G>C p.K714N (on ENST00000676171; = p.K673N on NM_004570.5) | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.347); catalogued as COSV56803597; called by muse, mutect2, varscan2
- POTEE | c.2320G>A p.G774S | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.944); catalogued as rs571289203, COSV100387337; called by muse, mutect2, varscan2
- RBMS3 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 101/310 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.701); catalogued as rs745458478, COSV56138386; called by muse, mutect2, varscan2
- RYR2 | c.11429G>A p.R3810Q | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1473957175, COSV63661073; called by muse, varscan2
- SCN7A | c.598G>T p.D200Y | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV69270363; called by muse, mutect2, varscan2
- SGSM3 | c.1271A>G p.K424R | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50651584; called by muse, mutect2, varscan2
- SLC5A4 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs1469131886, COSV56669408; called by muse, mutect2, varscan2
- SPAG4 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV65330697; called by muse, mutect2
- SPDEF | c.440C>G p.P147R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65000782; called by muse, mutect2, varscan2
- SYNE2 | c.2356A>G p.R786G | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs1415400238, COSV59945166; called by muse, mutect2, varscan2
- TRMT1 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.09); catalogued as rs781032710, COSV53399902; called by muse, mutect2, varscan2
- ZFR2 | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.129); catalogued as rs371712225; called by muse, mutect2
- ARFGEF3 | c.339G>T p.V113= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV52454153; called by muse, varscan2
- BAHD1 | c.381C>T p.L127= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV69083772; called by muse, mutect2, varscan2
- CHORDC1 | c.111A>G p.L37= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs1425256840, COSV57705702; called by muse, mutect2, varscan2
- ELF4 | c.1773G>A p.P591= | Silent (SNP) | VAF 111/185 reads (60%) | catalogued as rs750436474, COSV57451776; called by muse, mutect2, varscan2
- GABRA4 | c.798G>A p.P266= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as rs541280213, COSV51925155; called by muse, mutect2, varscan2
- GABRA5 | c.648G>A p.A216= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as rs778210544, COSV59476246; called by muse, mutect2, varscan2
- GAS2L2 | c.853C>T p.L285= | Silent (SNP) | VAF 138/386 reads (36%) | called by muse, varscan2
- KLRK1 | c.609T>C p.C203= | Silent (SNP) | VAF 92/303 reads (30%) | catalogued as COSV53698245; called by muse, mutect2, varscan2
- NLRP2 | c.1620C>T p.S540= | Silent (SNP) | VAF 59/171 reads (35%) | catalogued as rs190374903; called by muse, mutect2, varscan2
- PCDHA13 | c.2055C>T p.G685= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as COSV56482120; called by muse, mutect2, varscan2
- PCIF1 | c.786C>T p.S262= | Silent (SNP) | VAF 56/237 reads (24%) | catalogued as COSV65026252; called by muse, mutect2, varscan2
- PLG | c.957G>A p.L319= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as COSV51981884, COSV51987235; called by muse, mutect2, varscan2
